Somatic mutation profile of tumor specimen TCGA-BA-6871-01A (aliquot TCGA-BA-6871-01A-11D-1870-08) from TCGA case TCGA-BA-6871, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-BA-6871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f82917e-7f5d-4d17-9753-51c3c2b11332.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6871-10A (Blood Derived Normal), aliquot TCGA-BA-6871-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f761205b-0f7c-4acc-8cc9-0e04747e8338

The open-access MAF lists 148 somatic variants for this specimen: 113 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 32, Splice Site 6, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, Splice Region 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PMS2 | c.164-1G>C p.X55_splice | Splice Site (SNP) | VAF 34/114 reads (30%) | catalogued as rs763308607, COSV99763916; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV51844615; called by muse, mutect2, varscan2
- ALMS1 | c.7792G>C p.D2598H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV100041294; called by muse, mutect2, varscan2
- ALPG | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99779170; called by muse, mutect2, varscan2
- ANK2 | c.5539C>A p.P1847T | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV52162999, COSV99999946; called by muse, mutect2, varscan2
- ANKRD30A | c.1926C>G p.F642L (on ENST00000611781; = p.F586L on NM_052997.2) | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557264466, COSV100652988, COSV64605804, COSV64615083; called by muse, mutect2, varscan2
- ANKS1A | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV100832114; called by muse, mutect2, varscan2
- ARCN1 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.304); catalogued as rs1555077420, COSV50614440; called by muse, mutect2, varscan2
- ATG16L1 | c.1751C>T p.A584V (on ENST00000392017 / NM_030803.7; = p.A565V on NM_017974.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs756788551, COSV61467337; called by muse, mutect2, varscan2
- ATP10A | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV100790921; called by muse, mutect2, varscan2
- C20orf194 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99330322; called by muse, mutect2, varscan2
- C9orf50 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100992302; called by muse, mutect2, varscan2
- CARD11 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs775081227, COSV100712209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC87 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100039766; called by muse, mutect2, varscan2
- CENPC | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99893566; called by muse, mutect2, varscan2
- CHRD | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99200246; called by muse, mutect2, varscan2
- CHRNG | c.1510C>G p.P504A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99298961; called by muse, mutect2, varscan2
- COL5A3 | c.1376T>A p.V459D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV99318275; called by muse, mutect2, varscan2
- CPNE2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as rs548667012, COSV99321250; called by muse, mutect2, varscan2
- CRTAM | c.347-1G>T p.X116_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99911788; called by muse, mutect2, varscan2
- DDI1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142985363; called by muse, mutect2, varscan2
- DDX56 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770985431, COSV51838208; called by muse, mutect2, varscan2
- DENND6A | c.276A>G p.E92= | Splice Region (SNP) | VAF 42/57 reads (74%) | catalogued as COSV100231288; called by muse, mutect2, varscan2
- DHX36 | c.1092G>T p.L364F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419677023, COSV100273350; called by muse, mutect2, varscan2
- DOCK3 | c.2878T>C p.F960L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV99809397; called by muse, mutect2, varscan2
- ERC1 | c.1708G>T p.E570* (on ENST00000360905 / NM_178040.4; = p.E542* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 16/348 reads (5%) | catalogued as COSV100705636; called by muse, mutect2
- FAT1 | c.9092C>T p.T3031I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV101499100; called by muse, mutect2, varscan2
- FBN2 | c.8415G>A p.M2805I | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99325200; called by muse, mutect2, varscan2
- FHL3 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100885077; called by muse, mutect2
- FHL5 | c.751A>G p.N251D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.735); catalogued as COSV100459173, COSV58736939; called by muse, mutect2
- GLT6D1 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV100874504, COSV65627590; called by muse, mutect2, varscan2
- GPR25 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs200739616, COSV100421681, COSV58498010; called by muse, mutect2
- GPR26 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs1222063125, COSV52932668; called by muse, mutect2
- GPR32 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as COSV99567085; called by muse, mutect2, varscan2
- GRIK2 | c.2549C>A p.A850D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV100023417; called by muse, mutect2, varscan2
- GRIN2A | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771127161, COSV100408468; called by muse, mutect2, varscan2
- GRIN3A | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701377, COSV62451696; called by muse, mutect2, varscan2
- GRIN3A | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868638738, COSV62451702; called by muse, mutect2, varscan2
- HERC2 | c.14102T>C p.I4701T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV99871282; called by muse, mutect2, varscan2
- HIP1 | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782712426, COSV61190764; called by muse, mutect2, varscan2
- IFT172 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs144121974; called by muse, mutect2, varscan2
- IKZF1 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV100497997; called by muse, mutect2, varscan2
- INPP5B | c.802A>T p.N268Y (on ENST00000373023; = p.N188Y on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100886388; called by muse, mutect2, varscan2
- IPO5 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99847025; called by muse, mutect2, varscan2
- IQCN | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs1341402831, COSV101148382, COSV66574884; called by muse, mutect2, varscan2
- KCNQ3 | c.1451G>T p.W484L | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.251); catalogued as COSV101195693; called by muse, mutect2, varscan2
- KCTD16 | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV101568744; called by muse, mutect2, varscan2
- KIFAP3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100846735; called by muse, mutect2, varscan2
- KLHDC3 | c.415A>C p.I139L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV99763577; called by muse, mutect2, varscan2
- KMT2D | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM122087, CM146860, COSV99977967; called by muse, mutect2, varscan2
- LRP1B | c.13046C>T p.T4349M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs773522720, COSV101253137; called by muse, mutect2, varscan2
- LRP1B | c.11195C>T p.S3732L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs373553527; called by muse, mutect2, varscan2
- LRP5 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.311); catalogued as rs760090713, COSV53718909, COSV99591485; called by muse, mutect2, varscan2
- LRRN3 | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100068111; called by muse, mutect2, varscan2
- METTL21A | c.382A>C p.N128H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV99777669; called by muse, mutect2, varscan2
- NBEA | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100077108, COSV100085324, COSV59785443; called by muse, mutect2, varscan2
- NCAPD2 | c.3729G>C p.M1243I | Missense Mutation (SNP) | VAF 416/505 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV57521777, COSV99975403; called by muse, mutect2, varscan2
- NOL8 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs375437538; called by muse, mutect2, varscan2
- NRP1 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV99587837; called by muse, mutect2, varscan2
- OR3A2 | c.941T>G p.F314C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV101375037; called by muse, mutect2, varscan2
- OR8J3 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs752527178, COSV100040568, COSV56883183; called by muse, mutect2, varscan2
- OR8K5 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2, varscan2
- OTOGL | c.2347G>A p.E783K (on ENST00000547103; = p.E774K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.093); catalogued as COSV101509026; called by muse, mutect2, varscan2
- OVGP1 | c.1735A>G p.R579G | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100868016; called by muse, mutect2, varscan2
- PARS2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs879231179, COSV64883672; called by muse, mutect2
- PCLO | c.5143G>C p.E1715Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100427793; called by muse, mutect2, varscan2
- PIK3AP1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100225525; called by muse, mutect2, varscan2
- PKD1L1 | c.3218A>G p.Y1073C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99218579; called by muse, mutect2, varscan2
- PPP4R3A | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100465621; called by muse, mutect2, varscan2
- PRDM8 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100324956; called by muse, mutect2, varscan2
- PRDX4 | c.600-1G>A p.X200_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV101028595; called by muse, mutect2, varscan2
- PSIP1 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as COSV101050896; called by muse, mutect2, varscan2
- PSMC3 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.741); catalogued as COSV100099321; called by muse, mutect2, varscan2
- PSTK | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs747980417, COSV100924778; called by muse, mutect2, varscan2
- PTPRD | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV100643534; called by muse, mutect2, varscan2
- PTPRU | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV100111792; called by muse, mutect2, varscan2
- RCC1 | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100868066, COSV65778885; called by muse, mutect2, varscan2
- REEP5 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758022891, COSV99809527; called by muse, mutect2, varscan2
- RIMBP2 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99898475; called by muse, mutect2, varscan2
- ROBO2 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV100164479; called by muse, mutect2, varscan2
- RPTOR | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV100155265; called by muse, mutect2, varscan2
- SAMD4B | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100080080; called by muse, mutect2, varscan2
- SGIP1 | c.1351G>C p.V451L | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761801425, COSV99390577, COSV99393458; called by muse, varscan2
- SLC15A2 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.359); catalogued as COSV99815116; called by muse, mutect2, varscan2
- SMC4 | c.2160C>G p.N720K | Missense Mutation (SNP) | VAF 57/489 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100643945; called by muse, mutect2, varscan2
- STAT2 | c.1116-2A>T p.X372_splice | Splice Site (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100028625; called by muse, mutect2, varscan2
- THG1L | c.736-2A>T p.X246_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99180222; called by muse, mutect2, varscan2
- THSD7B | c.4127C>G p.T1376R (on ENST00000272643; = p.T1374R on NM_001316349.2) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV99744989; called by muse, mutect2, varscan2
- TPO | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100219818, COSV61102596; called by muse, mutect2, varscan2
- TRIM26 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV101359426, COSV68962963; called by muse, mutect2, varscan2
- TRIP10 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100504901; called by muse, mutect2, varscan2
- UBE4A | c.2588-1G>A p.X863_splice (on ENST00000252108 / NM_001204077.2; = p.X870_splice on NM_004788.4) | Splice Site (SNP) | VAF 26/118 reads (22%) | catalogued as COSV52807743, COSV99347891; called by muse, mutect2, varscan2
- UGT1A7 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV100691965, COSV60839375; called by muse, mutect2, varscan2
- UPF2 | c.2958G>T p.K986N | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); catalogued as COSV100706961, COSV100707105; called by muse, varscan2
- USH2A | c.14174G>A p.W4725* | Nonsense Mutation (SNP) | VAF 67/364 reads (18%) | catalogued as CM165984, COSV100229628; called by muse, mutect2, varscan2
- USH2A | c.11012C>T p.P3671L | Missense Mutation (SNP) | VAF 181/208 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100229630; called by muse, mutect2, varscan2
- WASHC2C | c.3163G>A p.E1055K (on ENST00000336378; = p.E1034K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1180693308; called by muse, mutect2, varscan2
- WIPF3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54206480, COSV54208401; called by muse, mutect2, varscan2
- YEATS2 | c.2378C>G p.S793C | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1305758136, COSV100527498; called by muse, mutect2, varscan2
- ZFAND3 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV99764621; called by muse, mutect2, varscan2
- ZKSCAN2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100047830; called by muse, mutect2, varscan2
- ZNF12 | c.897T>A p.C299* (on ENST00000405858 / NM_016265.4; = p.C261* on NM_006956.3) | Nonsense Mutation (SNP) | VAF 75/133 reads (56%) | catalogued as COSV100703571; called by muse, mutect2, varscan2
- ZNF383 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100776733; called by muse, mutect2, varscan2
- ZNF594 | c.2405G>C p.R802T | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101280369; called by muse, mutect2, varscan2
- ZNF624 | c.711G>C p.L237F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100257030; called by muse, mutect2, varscan2
- ZNF639 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV100418383; called by muse, mutect2, varscan2
- ZSWIM2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294263745, COSV54579553, COSV99720609; called by muse, mutect2, varscan2
- DUSP5 | c.691del p.E231Kfs*16 | Frame Shift Del (DEL) | VAF 65/156 reads (42%) | called by mutect2, pindel, varscan2
- NCOA7 | c.1055_1059del p.E352Vfs*25 | Frame Shift Del (DEL) | VAF 48/115 reads (42%) | called by mutect2, pindel, varscan2
- OR11H1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- SI | c.3811dup p.I1271Nfs*3 | Frame Shift Ins (INS) | VAF 136/436 reads (31%) | called by mutect2, pindel, varscan2
- TRAJ23 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- ZNF41 | c.2338_2339del p.*780Rfs*42 | Frame Shift Del (DEL) | VAF 63/98 reads (64%) | called by mutect2, pindel, varscan2
- AKAP9 | c.6330T>C p.H2110= (on ENST00000359028; = p.H2078= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100661950; called by muse, mutect2, varscan2
- AP002512.3 | c.420C>T p.I140= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99687783; called by muse, mutect2, varscan2
- C1orf94 | c.1170C>T p.A390= (on ENST00000488417 / NM_001134734.2; = p.A200= on NM_032884.5) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs375613990; called by muse, mutect2
- CCDC114 | c.1764C>T p.F588= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs770653800, COSV100196404; called by muse, mutect2, varscan2
- CGNL1 | c.2745G>A p.Q915= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as COSV99847547; called by muse, mutect2, varscan2
- CPNE2 | c.391C>T p.L131= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99321249; called by muse, mutect2, varscan2
- CRYBG2 | c.4242C>T p.G1414= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs763397390, COSV57483657; called by muse, mutect2, varscan2
- CTNNA2 | c.306G>A p.T102= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs373823087, COSV63565154; called by muse, mutect2, varscan2
- DNAAF2 | c.2035C>T p.L679= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs953564439, COSV100023840; called by muse, varscan2
- EGFL8 | c.627C>T p.R209= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs770147884, COSV100246827; called by muse, mutect2, varscan2
- GSTA4 | c.522C>T p.I174= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1391838802, COSV100919793; called by muse, mutect2, varscan2
- HECA | c.1434C>T p.T478= | Silent (SNP) | VAF 15/177 reads (8%) | catalogued as COSV100866156; called by muse, mutect2
- HUWE1 | c.2634C>T p.G878= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99470785; called by muse, mutect2, varscan2
- IFT80 | c.1815G>C p.V605= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV100424410; called by muse, mutect2
- IKZF1 | c.468G>A p.Q156= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58781106; called by muse, mutect2, varscan2
- JAK3 | c.2856C>A p.A952= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV101512884; called by muse, mutect2, varscan2
- KDM3A | c.3393C>G p.V1131= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100460035, COSV100460798; called by muse, mutect2, varscan2
- KIAA1109 | c.13347C>T p.I4449= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99145969; called by muse, mutect2, varscan2
- NYAP2 | c.1305C>T p.T435= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1182623025, COSV99795842; called by muse, mutect2, varscan2
- PAK2 | c.420G>C p.L140= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV59079327; called by muse, mutect2, varscan2
- PPP2R5E | c.837C>G p.L279= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100518335; called by muse, mutect2, varscan2
- PRAME | c.366G>C p.L122= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV101287016; called by muse, mutect2, varscan2
- PRDM8 | c.237A>C p.A79= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100324953; called by muse, mutect2, varscan2
- SETBP1 | c.1035G>A p.Q345= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs762717804, COSV99952173; called by muse, mutect2, varscan2
- SIK2 | c.582A>G p.E194= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100515971; called by muse, mutect2, varscan2
- SLITRK3 | c.2682C>A p.P894= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV99578562; called by muse, mutect2, varscan2
- SLITRK5 | c.2445G>A p.L815= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1271705827, COSV100280366; called by muse, mutect2, varscan2
- SUN1 | c.2468G>A p.*823= (on ENST00000405266 / NM_001367651.1; = p.*703= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99768434; called by muse, mutect2, varscan2
- TBX15 | c.378C>T p.F126= (on ENST00000369429 / NM_001330677.2; = p.F20= on NM_152380.3) | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99253649; called by muse, mutect2, varscan2
- TERT | c.3309G>T p.L1103= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as COSV99716634; called by muse, mutect2
- VPS26B | c.18C>T p.F6= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs975314478, COSV99844809; called by muse, mutect2, varscan2
- ZBTB7B | c.438A>C p.L146= (on ENST00000292176; = p.L180= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/87 reads (63%) | catalogued as COSV99420811; called by muse, mutect2, varscan2
- FAM13A | c.1008-17948C>G | Intron (SNP) | VAF 43/180 reads (24%) | catalogued as COSV99982914; called by muse, mutect2, varscan2
- NPR3 | c.*3330C>A | 3'UTR (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99422345; called by muse, mutect2, varscan2
- RPGR | c.2520+1279G>C | Intron (SNP) | VAF 40/71 reads (56%) | catalogued as COSV100139635, COSV58832174; called by muse, mutect2, varscan2
